MMRF case MMRF_1201 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5a19a420-4182-4767-b8d6-c520218ad41a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.3 years (24,577 days); ISS stage: II; Days to last known disease status: 1,694 days (4.6 years); Days to last follow up: 1,694 days (4.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 63 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 31 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 50 days; Days to treatment end: 54 days.
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 71 days; Days to treatment end: 148 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 71 days; Days to treatment end: 196 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 197 days; Days to treatment end: 197 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 436 days (1.2 years); Days to treatment end: 513 days (1.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 643 days (1.8 years); Days to treatment end: 789 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 790 days (2.2 years); Days to treatment end: 923 days (2.5 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,007 days (2.8 years); Days to treatment end: 1,034 days (2.8 years).
   Treatment given: Therapeutic agents: Carfilzomib + Panobinostat; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,034 days (2.8 years); Days to treatment end: 1,356 days (3.7 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,392 days (3.8 years); Days to treatment end: 1,422 days (3.9 years).
   Treatment given: Therapeutic agents: Daratumumab + Lenalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,430 days (3.9 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,694.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 1): M Protein 5.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 77.3 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 2.93 µg/mL; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 30 g/L; Total Protein 11.6 g/dL; Glucose 5.06 mmol/L.
- Day 71: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 7.29 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.14 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 4.84 mmol/L.
- Day 194: M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.46 mg/dL; Immunoglobulin G 7.05 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.68 µg/mL; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 62.7 ×10⁹/L; Absolute Neutrophil 61.6 ×10⁹/L; Platelets 11 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L.
- Day 267 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.51 mg/dL; Immunoglobulin G 9.18 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.56 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.62 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 4.51 mmol/L.
- Day 359 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 6.75 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.28 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 33 g/L; Total Protein 5.9 g/dL; Glucose 4.62 mmol/L.
- Day 440 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.17 mmol/L.
- Day 517 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.67 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 54.8 µmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.06 mmol/L.
- Day 643 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 13.6 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.64 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.06 mmol/L.
- Day 736 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.49 mg/dL; Immunoglobulin G 15.8 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.79 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 4.62 mmol/L.
- Day 790 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 24 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.32 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7.6 g/dL; Glucose 4.79 mmol/L.
- Day 888 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 17.7 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.69 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 4.73 mmol/L.
- Day 923 (ECOG 0): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 18.6 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.91 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 5.39 mmol/L.
- Day 1,044 (ECOG 0): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 28.7 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.1 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.98 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 8.2 g/dL; Glucose 5.06 mmol/L.
- Day 1,121 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 8.87 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.94 ×10⁹/L; Platelets 64 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.43 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 6.33 mmol/L.
- Day 1,232 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 9.31 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.05 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.18 mmol/L.
- Day 1,316 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.34 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 5.23 mmol/L.
- Day 1,419 (ECOG 0): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 31.5 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 6.06 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 8.3 g/dL; Glucose 5.23 mmol/L.
- Day 1,521 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 7.05 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.1 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.49 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 32 g/L; Total Protein 5.8 g/dL; Glucose 4.79 mmol/L.
- Day 1,605: M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 8.48 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.09 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.01 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 5.34 mmol/L.
- Day 1,689 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.71 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 5.01 mmol/L.

Other clinical attributes
- Day -2: Weight: 55 kg; Height: 165 cm.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples)
- Sample MMRF_1201_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1201_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
- Sample MMRF_1201_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 736 days (2.0 years).
- Sample MMRF_1201_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,419 days (3.9 years).
